FM case AD301 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/c303700c-cb1f-4fbe-bff5-7460e7a0c23d

Male, 78.3 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
